Gene-level copy-number profile of specimen HCM-SANG-0779-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-0779-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS.
Specimen HCM-SANG-0779-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 100e5088-8c76-45d0-96a6-4587271af9b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0779-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/915df64c-8606-418b-b8f3-b526d6058f90

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,030; copy number 2: 21,568; copy number 3: 27,544; copy number 4: 7,413; copy number 5: 715; copy number 6: 111; copy number 7: 2; copy number 8: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:126,556,323–127,419,050, 1 gene, copy number 8 (within-gene range 4–8): PCAT1.
- chr8:127,072,694–127,742,951, 10 genes, copy number 8: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr12:55,927,319–55,954,027, 2 genes, copy number 7 (within-gene range 6–7): DGKA, AC025162.2.

Autosomal genes at a single copy (total copy number 1): 1,030. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
